Gene-level copy-number profile of tumor specimen C3L-02967-01 from CPTAC case C3L-02967, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA2; Tumor grade: G1; Age at diagnosis: 74.4 years (27,172 days).
Specimen C3L-02967-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6ed17b64-fb1f-4dc9-8b74-a204bf881dd4.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-02967-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/8d1e0752-5e7f-4943-a589-9f97abcec790

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8,189; copy number 1: 2,059; copy number 2: 42,709; copy number 3: 2; copy number 4: 4,752; copy number 6: 683; copy number 7: 3.

Caution: 8,189 autosomal genes are at 0 copies in this file, far more than a typical tumor; the lists below are given as recorded.

Homozygous deletions (total copy number 0; autosomes only): 8,189 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,857,267–15,118,043, 272 genes (within-gene range 0–2) (broad region; genes not listed).
- chr1:15,526,813–17,201,733, 91 genes (broad region; genes not listed).
- chr1:18,595,414–19,312,146, 17 genes: AL031737.1, PAX7, TAS1R2, ALDH4A1, MIR4695, MIR1290, IFFO2, AL137127.1, UBR4, EMC1-AS1, EMC1, MRTO4, AKR7L, AKR7A3, AL035413.1, AKR7A2, RNU6-1099P.
- chr1:47,179,250–121,580,524, 1,284 genes (within-gene range 0–2) (broad region; genes not listed).
- chr1:149,018,671–149,747,818, 21 genes (within-gene range 0–4): AC239802.2, AC239804.1, NBPF9, AC239804.2, RNVU1-24, AC245297.3, AC245297.1, AC245297.2, 7SK, SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19, PPIAL4C, LINC00869, AC242842.2, AC242842.1, RNVU1-30, FAM91A2P, AC243772.3, RNU1-68P.
- chr5:66,298,394–80,256,048, 268 genes (broad region; genes not listed).
- chr5:88,883,328–95,961,851, 82 genes (within-gene range 0–4) (broad region; genes not listed).
- chr5:96,525,267–181,342,213, 1,508 genes (within-gene range 0–4) (broad region; genes not listed).
- chr7:127,346,790–127,618,142, 9 genes: ZNF800, AC000123.2, AC000123.1, AC000123.3, AC000124.1, GCC1, ARF5, FSCN3, PAX4.
- chr8:64,091–12,087,445, 290 genes (broad region; genes not listed).
- chr8:12,333,644–65,634,217, 883 genes (broad region; genes not listed).
- chr8:72,196,334–72,938,349, 10 genes: AC078906.1, AC022905.1, RNA5SP271, AC124293.1, AC011131.1, KCNB2, HAUS1P3, AC013562.2, AC013562.1, AC090735.1.
- chr9:12,134–40,153,147, 672 genes (broad region; genes not listed).
- chr19:186,373–18,522,116, 1,011 genes (broad region; genes not listed).
- chr19:39,083,913–43,536,130, 233 genes (broad region; genes not listed).
- chr19:44,950,044–58,605,223, 964 genes (broad region; genes not listed).
- chr20:33,079,644–57,568,121, 574 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 686 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:12,310–38,133, 3 genes, copy number 7: DDX11L8, WASH8P, FAM138D.
- chr19:27,638,483–39,032,785, 393 genes, copy number 6 (broad region; genes not listed).
- chr19:43,543,311–44,949,565, 82 genes, copy number 6 (broad region; genes not listed).
- chr20:57,599,695–64,327,972, 208 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,059. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
